Gene-level copy-number profile of tumor specimen TCGA-VR-AA7I-01A from TCGA case TCGA-VR-AA7I, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 70.8 years (25,855 days).
Specimen TCGA-VR-AA7I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.d0c943d3-2ff0-436c-a1ad-2b2495f6f527.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-AA7I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/eba545d6-efa8-4d54-998c-4e18942f4573

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 1,085; copy number 2: 14,030; copy number 3: 26,449; copy number 4: 13,438; copy number 5: 2,151; copy number 6: 1,138; copy number 7: 194; copy number 8: 443; copy number 9: 535; copy number 11: 231; copy number 12: 5; copy number 13: 1; copy number 16: 9; copy number 19: 1; copy number 20: 35; copy number 21: 16; copy number 32: 38.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:151,102,751–151,325,605, 1 gene (within-gene range 0–2): SH3D19.
- chr4:151,259,503–151,670,503, 8 genes (within-gene range 0–2): AC104819.1, PRSS48, AC104819.2, RNU6-1282P, AC104819.3, FAM160A1-DT, FAM160A1, RN7SKP35.
- chr8:28,890,395–29,064,764, 1 gene (within-gene range 0–2): HMBOX1.
- chr8:28,949,676–29,056,685, 3 genes: HMBOX1-IT1, RNA5SP260, AC108449.2.
- chr8:29,067,279–29,068,454, 1 gene: AC108449.3.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene: AL449423.1.
- chr11:16,484,084–16,484,671, 1 gene: AKR1B1P3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,508 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:187,291,272–191,952,826, 52 genes, copy number 7: AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2.
- chr3:192,139,395–193,697,811, 18 genes, copy number 7: FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA.
- chr5:58,198–16,180,762, 281 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr5:16,373,361–16,681,905, 7 genes, copy number 8: LINC02150, AC020980.1, ZNF622, RETREG1, AC024588.1, AC022113.1, Y_RNA.
- chr7:116,524,994–120,227,213, 54 genes, copy number 21–32: CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8, ANKRD7, AC002529.1, GTF3AP6, AC092098.1, AC079791.1, LINC02476, RNU1-29P, AC004946.1, AC004946.2.
- chr11:66,070,272–71,252,577, 200 genes, copy number 8–20 (within-gene range 2–20) (broad region; genes not listed).
- chr14:18,333,726–40,390,547, 703 genes, copy number 7–11 (broad region; genes not listed).
- chr14:62,604,113–63,102,037, 2 genes, copy number 7 (within-gene range 6–7): ATP5F1AP4, KCNH5.
- chr14:82,788,478–82,796,221, 1 gene, copy number 19: AL355095.1.
- chr15:23,912,411–26,477,840, 123 genes, copy number 9–12 (broad region; genes not listed).
- chr15:26,557,598–26,658,763, 2 genes, copy number 12: AC009878.1, AC011196.1.
- chr18:596,988–927,993, 20 genes, copy number 7 (within-gene range 4–7): CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904.
- chr18:33,851,100–36,279,119, 45 genes, copy number 11: NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3.

Autosomal genes at a single copy (total copy number 1): 202. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
